Somatic mutation profile of tumor specimen TCGA-EB-A5SF-01A (aliquot TCGA-EB-A5SF-01A-11D-A30X-08) from TCGA case TCGA-EB-A5SF, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Nodular melanoma; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 78.8 years (28,772 days).
Specimen TCGA-EB-A5SF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7e36b9b3-c262-4547-ba7d-6f6367d79a06.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EB-A5SF-10A (Blood Derived Normal), aliquot TCGA-EB-A5SF-10A-01D-A30X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/50c7253b-86b5-423a-8fdb-12b33df231b4

The open-access MAF lists 36 somatic variants for this specimen: 23 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 12, Frame Shift Ins 2, Splice Site 2, Nonsense Mutation 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.8615A>C p.E2872A | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.011); catalogued as COSV71292852; called by muse, mutect2, varscan2
- ANAPC2 | c.22G>T p.A8S | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.003); catalogued as COSV58808702; called by muse, mutect2, varscan2
- ARFGEF3 | c.1672G>A p.D558N | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.462); catalogued as COSV52467324; called by muse, mutect2, varscan2
- C1S | c.1049C>T p.S350F | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as COSV61072022; called by muse, mutect2, varscan2
- CBLC | c.779+1G>C p.X260_splice | Splice Site (SNP) | VAF 19/39 reads (49%) | catalogued as rs1394074209, COSV54325072; called by muse, mutect2, varscan2
- CDH18 | c.642A>C p.T214= | Splice Region (SNP) | VAF 53/656 reads (8%) | catalogued as COSV56951256; called by muse, mutect2
- CDK5RAP2 | c.278A>G p.H93R | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as rs755655281, COSV62577141; called by muse, mutect2, varscan2
- CLPTM1 | c.586+2T>C p.X196_splice | Splice Site (SNP) | VAF 26/73 reads (36%) | catalogued as COSV61612713; called by muse, mutect2, varscan2
- MYBPC1 | c.2993G>A p.G998E (on ENST00000550270 / NM_206820.2; = p.G1005E on NM_002465.4) | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62256503; called by muse, mutect2, varscan2
- NOTCH2 | c.5374C>T p.Q1792* | Nonsense Mutation (SNP) | VAF 33/312 reads (11%) | catalogued as COSV56701651; called by muse, mutect2, varscan2
- OR4N2 | c.494G>C p.R165P | Missense Mutation (SNP) | VAF 30/166 reads (18%) | SIFT tolerated (0.8); PolyPhen benign (0.015); catalogued as COSV60050197, COSV60054028; called by muse, mutect2, varscan2
- OSMR | c.2265C>G p.I755M | Missense Mutation (SNP) | VAF 49/248 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.624); catalogued as COSV57090054; called by muse, varscan2
- OSMR | c.2380C>G p.L794V | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.034); catalogued as COSV57090083; called by muse, varscan2
- OSMR | c.2579C>G p.T860S | Missense Mutation (SNP) | VAF 74/377 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV57090098; called by muse, mutect2, varscan2
- OSMR | c.2756C>T p.S919F | Missense Mutation (SNP) | VAF 38/205 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs762388647, COSV57090122; called by muse, varscan2
- RIMS1 | c.4579C>A p.Q1527K | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV53476486; called by muse, mutect2, varscan2
- SLITRK4 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT tolerated (0.97); PolyPhen possibly damaging (0.836); catalogued as COSV62025639; called by muse, mutect2, varscan2
- TERT | c.1882G>A p.D628N | Missense Mutation (SNP) | VAF 60/280 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1354825725, COSV57232830; ClinVar: uncertain significance; called by muse, varscan2
- TTN | c.99569C>T p.S33190L (on ENST00000591111; = p.S25766L on NM_003319.4) | Missense Mutation (SNP) | VAF 16/46 reads (35%) | PolyPhen benign (0.049); catalogued as COSV60266021; called by muse, mutect2, varscan2
- ZNF304 | c.1937A>G p.N646S | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs768099610, COSV56585931; called by muse, mutect2, varscan2
- ZNF397 | c.475T>A p.S159T | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV54352306; called by muse, mutect2, varscan2
- H2AC11 | c.154_155insA p.L52Hfs*71 | Frame Shift Ins (INS) | VAF 16/51 reads (31%) | called by mutect2, pindel, varscan2
- PRKAR1A | c.142_143insAT p.A48Dfs*82 | Frame Shift Ins (INS) | VAF 9/25 reads (36%) | called by mutect2, pindel, varscan2
- ADHFE1 | c.255C>G p.S85= | Silent (SNP) | VAF 56/194 reads (29%) | catalogued as COSV52558279; called by muse, mutect2, varscan2
- BASP1 | c.111G>A p.P37= | Silent (SNP) | VAF 5/49 reads (10%) | catalogued as rs767716479, COSV59470349; called by muse, mutect2
- C2 | c.762C>T p.N254= | Silent (SNP) | VAF 49/188 reads (26%) | catalogued as COSV54962101; called by muse, mutect2, varscan2
- DMRTC2 | c.963C>T p.I321= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as rs1555837205, COSV54187967; called by muse, mutect2, varscan2
- DSG2 | c.1711C>T p.L571= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV55201883; called by muse, mutect2, varscan2
- FPGS | c.297C>T p.I99= | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as COSV64676143; called by muse, mutect2, varscan2
- KCNA5 | c.717C>T p.I239= | Silent (SNP) | VAF 43/135 reads (32%) | catalogued as rs774064204, COSV52904785, COSV52905443; called by muse, mutect2, varscan2
- KYNU | c.804T>C p.D268= | Silent (SNP) | VAF 24/75 reads (32%) | catalogued as COSV51589568; called by muse, mutect2, varscan2
- OSMR | c.2322C>T p.I774= | Silent (SNP) | VAF 25/114 reads (22%) | catalogued as COSV57090067; called by muse, mutect2, varscan2
- OSMR | c.2680C>T p.L894= | Silent (SNP) | VAF 58/297 reads (20%) | catalogued as COSV57090108; called by muse, varscan2
- PCSK4 | c.1659C>T p.T553= | Silent (SNP) | VAF 21/44 reads (48%) | catalogued as rs202058018, COSV56300671, COSV99960647; called by muse, mutect2, varscan2
- TERT | c.2208G>A p.Q736= | Silent (SNP) | VAF 252/1018 reads (25%) | catalogued as COSV57232817; called by muse, mutect2, varscan2
- AC005863.1 | n.276G>A | RNA (SNP) | VAF 21/73 reads (29%) | catalogued as rs1282529087; called by muse, mutect2, varscan2
